Somatic mutation profile of tumor specimen 0DU81H from CCDI case PBCKTZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.1 years (3,705 days).
Specimen 0DU81H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ecfc750-f6b4-4ef8-a5da-6bc678e7cd08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU80F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/633c640c-3658-4617-8b96-344ca3fb3186

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Splice Region 2, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MICAL3 | c.5938C>T p.R1980W | Missense Mutation (SNP) | VAF 172/837 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs547316266; called by muse, varscan2
- ZNF215 | c.815G>T p.W272L | Missense Mutation (SNP) | VAF 103/528 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.435); catalogued as rs200618326; called by muse, varscan2
- OS9 | c.404-5T>A | Splice Region (SNP) | VAF 64/365 reads (18%) | called by muse, varscan2
- PDE1A | c.465G>A p.K155= | Splice Region (SNP) | VAF 150/314 reads (48%) | called by muse, varscan2
- GATAD2A | c.114A>G p.S38= | Silent (SNP) | VAF 88/560 reads (16%) | catalogued as rs1490554816; called by muse, varscan2
